Surgical pathology report (de-identified scan), TCGA case TCGA-IQ-7630, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Miami, specimen TCGA-IQ-7630-01A (Primary Tumor).

[page 1 of 6]
Pathologic Interpretation:

A. SOFT TISSUE TOOTH SOCKET #17:

INVASIVE CARCINOMA.

B. ALVEOLAR RIDGE LATERAL:

No malignancy seen.

C. BUCCAL MUCOSA INFERIOR:

No malignancy seen.

D. BUCCAL MUCOSA SUPERIOR:

No malignancy seen.

E. HARD PALATE:

No malignancy seen.

F. ANTERIOR TONSIL PILLAR:

No malignancy seen.

G. BASE OF TONGUE:

No malignancy seen.

H. LEFT MAXILLARY TUBEROSITY:

No malignancy seen.

I. LEFT FLOOR OF MOUTH:

No malignancy seen.

J. LINGUAL ALVEOLAR RIDGE OF MANDIBLE:

No malignancy seen.

K. BASE OF TONGUE DEEP:

No malignancy seen.

L. PTERYGOID:

No malignancy seen.

M. RETROMOLAR TRIGONE RESECTION WITH TOOTH #18 STITCH ANTERIOR SUPERIOR:

INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 3.5 cm with mucosal ulceration.

[page 2 of 6]
No Perineural nor lymphovascular space invasion identified.

Specimen margins are negative for tumor.

Tooth; for gross description only.

See tumor Summary.

N. PROXIMAL MANDIBLE:

No malignancy seen.

O. TISSUE MEDIAL TO PROXIMAL MANDIBLE:

INVASIVE CARCINOMA.

P. NARROW DISTAL MANDIBLE MARGIN:

No malignancy seen on frozen section.

Tissue did not survive processing for permanent section.

Q. ADDITIONAL TISSUE MEDIAL TO MANDIBLE:

No malignancy seen.

R. LEFT EXTERNAL JUGULAR NODE:

No malignancy seen in one lymph node (0/1).

S. LEFT NECK DISSECTION 2,3,4:

No malignancy seen in twenty-five lymph nodes (0/25).

T. TOOTH # 15, 16:

For gross description only.

U. LEFT NECK DISSECTION LEVEL 1:

No malignancy seen in one lymph node and salivary gland tissue (0/1).

V. ADDITIONAL PTERYGOID:

No malignancy seen.

W. SEGMENTAL MANDIBLE:

Pending decalcification.

X. LEFT MAXILLARY TUBEROSITY:

Pending decalcification.

Pathology Cancer Case Summary

Specimen: Oropharynx
Received: In formalin
Procedure: Resection
Other: Retromolar trigone resection

Specimen Integrity: Intact

Specimen Size: Greatest dimensions: 6 x 5 x 3 cm

Specimen Laterality: Left

Tumor Site: Oropharynx

Other (specify): Retromolar trigone

Tumor Laterality: Left

Tumor Focality: Single focus

Tumor Size:

Greatest dimension: 3.5 cm

Additional dimensions: 2.0 x 1.6 cm

[page 3 of 6]
Tumor Description: Ulcerated
Histologic Type: Squamous cell carcinoma, conventional
Histologic Grade: [REDACTED]: Poorly Differentiated
Margins:

Margins uninvolved by Invasive carcinoma

Lymph-Vascular Invasion: Not present

Perineural Invasion: Not identified

Primary Tumor (pT):

pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension

Regional Lymph Nodes (pN):

pN0: No regional lymph node metastasis

Specify:

Number examined: 27

Number involved: 0

Distant Metastasis (pM): Not applicable

As the attending pathologist, I attest that I: (i) Examined the relevant preparation(s) for the specimen(s); and (ii) Rendered the diagnosis(es).

Electronically Signed Out By

Procedures/Addenda Addendum

Addendum Diagnosis

W. SEGMENTAL MANDIBLE:

No malignancy seen in bone.

X. LEFT MAXILLARY TUBEROSITY:

No malignancy seen in bone.

Intraoperative Consultation

- A. SOFT TISSUE TOOTH SOCKET #17, FS: Carcinoma invasive
- B. ALVEOLAR RIDGE LATERAL, FS: No malignancy seen.
- C. BUCCAL MUCOSA INFERIOR, FS: No malignancy seen.
- D. BUCCAL MUCOSA SUPERIOR, FS: No malignancy seen.
- E. HARD PALATE, FS: Negative for malignancy.
- F. ANTERIOR TONSIL PILLAR, FS: Negative for malignancy.
- G. BASE OF TONGUE, FS: Negative for malignancy.

[page 4 of 6]
- H. LEFT MAXILLARY TUBEROSITY, FS: Negative for malignancy
- I. LEFT FLOOR OF MOUTH, FS: Negative for malignancy
- J. LINGUAL ALVEOLAR RIDGE OF MANDIBLE, FS: Negative for malignancy
- K. BASE OF TONGUE DEEP, FS: Negative for malignancy
- L. PTERYGOID, FS: Negative for malignancy.
- N. PROXIMAL MANDIBLE, FS: Negative for malignancy.
- O. TISSUE MEDIAL TO PROXIMAL MANDIBLE, FS: Infiltrating Squamous cell carcinoma
- P. NARROW DISTAL MANDIBLE MARGIN, FS: Negative for malignancy
- Q. ADDITIONAL TISSUE MEDIAL TO MANDIBLE, FS: Skeletal muscle; negative for malignancy

Clinical History:

None Provided

Operation Performed

Composite resection tracheostomy, free flap skin graft laryngoscopy

Pre Operative Diagnosis:

Malignant neoplasm of the mandible

Specimen(s) Received:

- A: SOFT TISSUE TOOTH SOCKET #17
- B: ALVEOLAR RIDGE LATERAL,
- C: BUCCAL MUCOSA INFERIOR
- D: BUCCAL MUCOSA SUPERIOR
- E: HARD PALATE
- F: ANTERIOR TONSIL PILLAR,
- G: BASE OF TONGUE
- H: LEFT MAXILLARY TUBEROSITY,
- I: LEFT FLOOR OF MOUTH,
- J: LINGUAL ALVEOLAR RIDGE OF MANDIBLE,
- K: BASE OF TONGUE DEEP,
- L: PTERYGOID
- M: RETROMOLAR TRIGONE RESECTION WITH TOOTH #18 STITCH ANTERIOR SUPERIOR
- N: PROXIMAL MANDIBLE,
- O: TISSUE MEDIAL TO PROXIMAL MANDIBLE,
- P: NARROW DISTAL MANDIBLE MARGIN,
- Q: ADDITIONAL TISSUE MEDIAL TO MANDIBLE,
- R: LEFT EXTERNAL JUGULAR NODE
- S: LEFT NECK DISSECTION 2,3,4
- T: TOOTH # 15, 16
- U: LEFT NECK DISSECTION LEVEL 1
- V: ADDITIONAL PTERYGOID
- W: SEGMENTAL MANDIBLE
- X: LEFT MAXILLARY TUBEROSITY

Gross Description:

- A. Received fresh labeled "Soft tissue tooth socket #17" is a piece of smooth tissue that measures 1.4 x 0.7 cm. Submitted in toto in one cassette for frozen section.
- B. Received fresh labeled "Alveolar ridge lateral" is a piece of smooth tissue, measuring 1.0 x 0.5 x 0.1 cm. Submitted in toto in one cassette for frozen section.

[page 5 of 6]
- C. Received fresh labeled "Buccal mucosa inferior" are two pieces of soft tissue, measuring 2.0 x 1.0 x 0.1 cm and the other one measures 0.4 x 0.3 x 0.1 cm. Both pieces are submitted in toto in one cassette for frozen section.
- D. Received fresh labeled "Buccal mucosa superior" is a piece of soft tissue that measures 1.5 x 1.2 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- E. Received fresh labeled "Hard palate" is a piece of soft tissue that measures 1.1 x 0.4 x 0.1 cm. Submitted in toto in one cassette for frozen section.
- F. Received fresh labeled "Anterior tonsil pillar" is piece of soft tissue that measures 2.0 x 1.0 x 0.1 cm. Submitted in toto in one cassette for frozen section.
- G. Received fresh labeled "Base of tongue" is a piece of soft tissue, measuring 2.0 x 1.2 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- H. Received fresh labeled "Left maxillary tuberosity" are two small pieces of soft tissue measuring 0.3 x 0.1 x 0.1 cm each. Submitted in toto in one cassette for frozen section.
- I. Received fresh labeled "Left floor or mouth" is a piece of soft tissue, measuring 1.0 x 0.4 x 0.1 cm. Submitted in toto in one cassette for frozen section.
- J. Received fresh labeled "Lingual alveolar ridge of mandible" are three pieces of soft tissue, measuring 0.1 cm in diameter each. Submitted in toto in one cassette for frozen section.
- K. Received fresh labeled "Base of tongue deep" is a piece of soft tissue that measures 1.2 x 1.0 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- L. Received fresh labeled "Pterygoid" is a fragmented piece of soft tissue that measures 2.8 x 1.8 x 0.3 cm. Submitted in toto in one cassette for frozen section.
- M. Received in formalin labeled "Retro molar trigone resection with tooth #18 stitch anterior superior" is a round piece of soft tissue, measuring 6.0 x 5.0 x 3.0 cm. It has a stitch also attached on the anterior superior margin, arbitrarily labeled as 12 o'clock. There is a tooth at 3 o'clock. There is tumor at the center of the specimen with a heaped up mucosa that measures 3.5 x 2.0 x 1.6 cm. A portion of the 12 o'clock area of the tumor is taken for tumor tissue bank. The specimen is inked as follows: From 12 to 6 o'clock – the edge is inked in black as well as the deep aspect of the specimen is also inked in black. From 6 o'clock to 12 o'clock it is inked in blue. The tumor is 1.0 cm away from the 3 o'clock margin, 0.3 cm away from the 6 o'clock, 0.8 cm away from the 9 o'clock margin and 0.8 cm from the 12 o'clock margin. Representative sections are taken and submitted as follows:
- | | |
|-------------|-------------------|
| Cassette #1 | 12 o'clock margin |
| Cassette #2 | 3 o'clock margin |
| Cassette #3 | 6 o'clock margin |
| Cassette #4 | 9 o'clock margin |
| Cassette #5 | Deep margin |
- N. Received fresh labeled "Proximal mandible" are four pieces of soft tissue. The largest one measure 0.5 x 0.3 x 0.1 cm and the smallest one measure 0.2 x 0.1 x 0.1 cm. Both of these specimens are submitted in toto in one cassette for frozen section.
- O. Received fresh labeled "Tissue medial to proximal mandible" is a piece of tissue measuring 1.5 x 0.7 x 0.2 cm. Submitted in toto in one cassette for frozen section.
- P. Received fresh labeled "Marrow, distal mandibular margin" is a tiny piece of soft tissue, measuring 0.1 x 0.1 x 0.1 cm. Submitted in toto in one cassette for frozen section.
- Q. Received fresh labeled "Additional tissue medial to mandible" is a piece of soft tissue, measuring 1.0 x 0.5 x 0.1 cm. Submitted in toto in one cassette.
- R. Received in formalin labeled "left external jugular node" is a hemorrhagic piece of soft tissue, measuring 1.5 x 1.0 x 0.5 cm. Bisected and submitted in toto in one cassette.
- S. Received in formalin labeled "left neck dissection 2,3,4" is a round piece of adipose tissue, measuring 6.0 x 4.5 x 2.0 cm. The surface is irregular, tan and hemorrhagic. Twenty-two lymph nodes are found. Two of them which are the largest measure 2.0 x 1.0 x 0.5 cm each and the smallest one measures 0.2 cm in diameter. Sections are submitted as follows:
- | | |
|----------------|-------------------------------------|
| Cassettes #1-5 | Bisected lymph nodes |
| Cassette #6 | Contains eight possible lymph nodes |
| Cassette #7 | Contains four lymph nodes |
| Cassette #8 | Contains seven possible lymph nodes |
- T. Received fresh labeled "Teeth #15, 16" are two teeth probably molars that measure 2.0 x 1.0 x 1.0 cm each. For gross description only.

[page 6 of 6]
- U. Received in formalin labeled "Left neck dissection" is a round pale yellow white hemorrhagic mass of adipose tissue that measures 5.5 x 4.0 x 3.0 cm. On cut section it seems like a salivary gland that measures 4.5 x 4.0 x 2.0 cm with no lymph nodes in side and any abnormalities macroscopically seen. Sections are submitted as follows:
- | | |
|-------------|--------------------------------|
| Cassette #1 | Contains a possible lymph node |
| Cassette #2 | Section from salivary gland |
- V. Received in formalin labeled "Additional pterygoid" is an irregular necrotic piece of tissue that measures 3.0 x 2.5 x 1.8 cm. The specimen is not oriented. Cross section reveals muscle and adipose tissue. No malignancy is grossly identified. No lymph nodes, no mucosa and no bones are identified. Representative sections in two cassettes.
- W. Received in formalin labeled "Segmental mandible" is an unoriented piece of mandible measuring 8.0 cm superior to inferior and 4.5 cm posterior to anterior and 2.0 cm medial to lateral. Sections are taken and submitted as follows:
- | | |
|-------------|--|
| Cassette #1 | Anterior margin |
| Cassette #2 | Contains posterior margin, two cassettes for decalcification |
- X. Received in formalin is an irregular piece of bone measuring 3.0 x 1.8 x 1.5 cm. No abnormal lesions are grossly identified. The specimen is and sections are submitted in one cassette for decalcification.

Source: NCI Genomic Data Commons file c9942655-68bc-4955-b441-d9fcbdf7a54b (TCGA-IQ-7630.656D8897-582C-4150-9D21-CBCDD281A540.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).